CPTAC case C3N-02997 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df2476c9-ebc4-42b8-b314-bd77cc22d7d8

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Dead; Days to death: 672 days (1.8 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 73.5 years (26,837 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 672 days (1.8 years); Progression or recurrence: yes; Days to last follow up: 672 days (1.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 6 cm); Lymph node involvement: Positive; Lymph nodes positive: 11; Lymph nodes tested: 19; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 370 days (1.0 years); Disease response: Progressive Disease; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 672 days (1.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 168 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 65 kg; Height: 176 cm; BMI: 20.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 73.5; Cigarettes per day: 30; Tobacco smoking onset year: 1968; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 54; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02997-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 226 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02997-21: Section location: Head; Percent tumor nuclei: 30; Percent necrosis: 5.
- Sample C3N-02997-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
